Somatic mutation profile of tumor specimen TCGA-TN-A7HJ-01A (aliquot TCGA-TN-A7HJ-01A-12D-A34J-08) from TCGA case TCGA-TN-A7HJ, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 51.5 years (18,809 days).
Specimen TCGA-TN-A7HJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2cb5fee0-a8ff-410d-8466-3f614e322103.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TN-A7HJ-10A (Blood Derived Normal), aliquot TCGA-TN-A7HJ-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39e8b9fc-24d9-4751-9987-f5f088e3d5c0

The open-access MAF lists 111 somatic variants for this specimen: 83 protein-altering or splice-affecting, 22 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 22, Nonsense Mutation 4, Frame Shift Del 4, 5'UTR 2, Frame Shift Ins 2, 3'UTR 2, In Frame Del 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.866_867dup p.R290Sfs*56 | Frame Shift Ins (INS) | VAF 22/75 reads (29%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- AAGAB | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 32/532 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99971832; called by muse, mutect2
- ACOT8 | c.507G>C p.K169N | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV99467435; called by muse, mutect2
- ARHGAP29 | c.1381C>A p.Q461K | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as COSV99557879; called by muse, mutect2, varscan2
- ARHGEF28 | c.1321G>T p.A441S | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.057); catalogued as COSV99708560; called by muse, mutect2, varscan2
- BUB1 | c.2671C>T p.Q891* | Nonsense Mutation (SNP) | VAF 10/148 reads (7%) | catalogued as COSV100241083, COSV57061890; called by muse, mutect2
- CCDC141 | c.2558C>T p.S853L | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99836505; called by muse, mutect2, varscan2
- CHD3 | c.3933G>C p.E1311D | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100390967; called by muse, mutect2
- CHRM3 | c.194T>A p.V65D | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV55087162, COSV99697900; called by muse, mutect2
- CNOT2 | c.1609C>T p.Q537* | Nonsense Mutation (SNP) | VAF 8/73 reads (11%) | catalogued as COSV57503661, COSV99972505; called by muse, mutect2, varscan2
- CYP2R1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.146); catalogued as COSV100584877; called by muse, mutect2, varscan2
- CYP7A1 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772557610, COSV56962137; called by muse, mutect2
- DAAM2 | c.1738C>A p.P580T | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99225131; called by muse, mutect2
- DEFB118 | c.346C>G p.L116V | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.003); catalogued as COSV53620573, COSV99489135, COSV99489262; called by muse, mutect2
- DOCK7 | c.6125A>G p.Q2042R (on ENST00000635253 / NM_001367561.1; = p.Q2011R on NM_033407.3) | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.375); catalogued as COSV99223691; called by muse, mutect2, varscan2
- EIF4A2 | c.593A>T p.Y198F | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV99961104; called by muse, mutect2
- EPHA10 | c.1582C>G p.Q528E | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as COSV100361153; called by muse, mutect2
- FAM135B | c.800C>A p.P267Q | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99421385; called by muse, mutect2
- FBXL5 | c.1987G>A p.D663N | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100377788, COSV58012885; called by muse, mutect2, varscan2
- FXYD7 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.039); catalogued as COSV99544776; called by muse, mutect2
- GDI1 | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 103/157 reads (66%) | SIFT tolerated (0.34); PolyPhen benign (0.076); catalogued as rs1458210975, COSV99340964; called by muse, mutect2, varscan2
- GGH | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99478797; called by muse, mutect2
- GOLGA2 | c.1399C>G p.L467V | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.553); catalogued as COSV101363094; called by muse, varscan2
- GPR149 | c.350T>C p.L117P | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV101078264; called by muse, mutect2
- GRIK1 | c.612G>T p.Q204H | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV100516327; called by muse, mutect2, varscan2
- GUCY1A2 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.26); catalogued as rs1313859382, COSV99972932; called by muse, mutect2, varscan2
- HELZ | c.2548G>C p.E850Q | Missense Mutation (SNP) | VAF 46/327 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.18); catalogued as COSV100698612; called by muse, mutect2, varscan2
- HNMT | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as rs199520450; called by muse, mutect2
- IDO1 | c.314G>A p.R105K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs12545877, COSV99503242; called by muse, mutect2
- IHH | c.479G>T p.R160L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99838635; called by muse, mutect2, varscan2
- JPH3 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as rs772600210, COSV52467539; called by muse, mutect2, varscan2
- KIAA1614 | c.704G>A p.S235N | Missense Mutation (SNP) | VAF 33/336 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100851286; called by muse, mutect2
- L3MBTL3 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.521); catalogued as COSV100695873, COSV100696369; called by muse, mutect2, varscan2
- LRP4 | c.2171G>T p.C724F | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101066439; called by muse, mutect2, varscan2
- LRRC7 | c.775G>A p.V259M (on ENST00000651989 / NM_001370785.2; = p.V226M on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.272); catalogued as COSV99225572; called by muse, mutect2, varscan2
- MCM6 | c.1442C>T p.T481I | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99918868; called by muse, mutect2, varscan2
- MEP1A | c.653C>T p.S218L | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100042519; called by muse, mutect2, varscan2
- MOSPD2 | c.674A>G p.E225G | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100996735; called by muse, mutect2, varscan2
- MROH2B | c.3882C>G p.I1294M | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.253); catalogued as COSV101270608, COSV68184281; called by muse, mutect2
- MYO10 | c.3567G>A p.M1189I | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99945033; called by muse, mutect2
- OR8J3 | c.301del p.L101Wfs*12 | Frame Shift Del (DEL) | VAF 29/229 reads (13%) | catalogued as COSV56880287; called by mutect2, pindel, varscan2
- PACS1 | c.727G>C p.V243L | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100269769; called by muse, mutect2
- PCDHB13 | c.355C>G p.Q119E | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as rs781928598, COSV99507027; called by muse, mutect2
- PHF20L1 | c.2994A>G p.I998M | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs1459540125, COSV99620840; called by muse, mutect2, varscan2
- PLXNB3 | c.2299G>A p.V767I | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT tolerated (0.21); PolyPhen benign (0.07); catalogued as rs782425266, COSV100737239; called by muse, mutect2, varscan2
- POLR2B | c.3296C>A p.A1099E | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV99825337; called by muse, mutect2, varscan2
- POLR3E | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV55402445; called by muse, mutect2, varscan2
- PPP1R16B | c.1601C>T p.S534L | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs1290376033, COSV55387267; called by muse, mutect2, varscan2
- RAC2 | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.317); catalogued as COSV99969426; called by muse, mutect2, varscan2
- RP1 | c.4325C>G p.P1442R | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV99606856, COSV99607893; called by muse, mutect2, varscan2
- SCUBE2 | c.312T>G p.N104K | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100496496; called by muse, mutect2
- SEMA3A | c.2114A>T p.D705V | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99545962; called by muse, mutect2, varscan2
- SLC14A2 | c.494T>A p.L165* | Nonsense Mutation (SNP) | VAF 25/172 reads (15%) | catalogued as COSV99675294; called by muse, mutect2, varscan2
- SLC38A1 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV101284136; called by muse, mutect2
- SLC7A11 | c.1306C>T p.L436F | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as rs149003210; called by muse, mutect2, varscan2
- SLCO1B1 | c.1701G>C p.L567F | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV99917767, COSV99918218; called by muse, mutect2
- SLTM | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV99989050; called by muse, mutect2
- SPATS2L | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.871); catalogued as COSV100660580; called by muse, mutect2
- SPTBN1 | c.955G>C p.E319Q | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV100442154; called by muse, mutect2
- SRCAP | c.8863T>C p.S2955P | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV99349710; called by muse, mutect2
- SSX2IP | c.1352G>A p.R451Q | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs748362670, COSV100642527; called by muse, mutect2
- TAOK2 | c.2455G>A p.E819K | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99664226; called by muse, mutect2
- TAS1R1 | c.2164G>C p.E722Q | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.043); catalogued as COSV100039572; called by muse, mutect2, varscan2
- TGFB3 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs547264290, COSV99472425; called by muse, mutect2
- TLR1 | c.135G>C p.Q45H | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.154); catalogued as rs1417201322, COSV100458399, COSV58303980; called by muse, mutect2
- TMTC1 | c.2146C>T p.Q716* (on ENST00000539277 / NM_001193451.2; = p.Q608* on NM_175861.3) | Nonsense Mutation (SNP) | VAF 10/134 reads (7%) | catalogued as COSV55481977; called by muse, mutect2
- TNFAIP8L2 | c.118G>C p.D40H | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100925304; called by muse, mutect2, varscan2
- TNNT2 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs483352832, CM087867, COSV99372143; ClinVar: uncertain significance / conflicting interpretations of pathogenicity / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TTC21B | c.2942G>A p.R981H | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.059); catalogued as rs142022626; called by muse, mutect2, varscan2
- VCAN | c.1228G>C p.V410L | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV99425223; called by muse, mutect2, varscan2
- VCAN | c.2212G>C p.E738Q | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as COSV99425228; called by muse, mutect2
- ZNF217 | c.3058C>G p.Q1020E | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as COSV100184314, COSV100184381; called by muse, mutect2, varscan2
- ZNF518A | c.1235C>T p.S412L | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782556513, COSV100283423; called by muse, mutect2, varscan2
- ZNF606 | c.1563C>G p.F521L | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100071676, COSV100071702; called by muse, mutect2
- ZNF646 | c.2089C>T p.R697W | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as rs781216621, COSV56219636; called by muse, mutect2, varscan2
- ZNF699 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1315955917, COSV100426899; called by muse, mutect2
- ZNF813 | c.1518del p.T508Hfs*235 | Frame Shift Del (DEL) | VAF 14/104 reads (13%) | catalogued as COSV67177250; called by mutect2, varscan2
- ADAM29 | c.789del p.K264Nfs*29 | Frame Shift Del (DEL) | VAF 18/142 reads (13%) | called by mutect2, pindel, varscan2
- NRXN2 | c.2045_2056del p.V682_C686delinsG | In Frame Del (DEL) | VAF 8/77 reads (10%) | called by mutect2, pindel
- PKP1 | c.1092_1093dup p.E365Gfs*47 | Frame Shift Ins (INS) | VAF 12/66 reads (18%) | called by mutect2, pindel, varscan2
- PLCB4 | c.2798del p.K933Rfs*7 | Frame Shift Del (DEL) | VAF 34/244 reads (14%) | called by mutect2, pindel, varscan2
- WASHC2C | c.3866C>G p.S1289C (on ENST00000336378; = p.S1268C on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ZNF658 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 42/303 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCY3 | c.3354C>T p.F1118= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs1177358605, COSV99567954; called by muse, mutect2, varscan2
- ARHGEF10 | c.4101G>A p.L1367= (on ENST00000398564; = p.L1342= on NM_014629.4) | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100034257; called by muse, mutect2, varscan2
- C6orf118 | c.984G>A p.T328= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs200182433, COSV57818218; called by muse, mutect2
- FCRL1 | c.105C>T p.T35= | Silent (SNP) | VAF 10/134 reads (7%) | catalogued as COSV100839748; called by muse, mutect2
- FLG | c.10896G>A p.Q3632= | Silent (SNP) | VAF 84/1526 reads (6%) | catalogued as rs767041129, COSV100911318; called by muse, mutect2
- GALNT13 | c.699C>T p.V233= | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as COSV67239313; called by muse, mutect2, varscan2
- GATA6 | c.1635G>A p.V545= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as COSV99333028; called by muse, mutect2, varscan2
- KANK2 | c.147C>T p.Y49= | Silent (SNP) | VAF 26/136 reads (19%) | catalogued as rs142504157; called by muse, mutect2, varscan2
- LAIR1 | c.477G>A p.L159= | Silent (SNP) | VAF 13/138 reads (9%) | catalogued as COSV100479550; called by muse, mutect2
- LRFN5 | c.444C>A p.A148= | Silent (SNP) | VAF 14/136 reads (10%) | catalogued as rs766394946, COSV53260986; called by muse, mutect2
- MMP2 | c.933G>A p.T311= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs776717466, COSV54601106, COSV99527590; called by muse, mutect2, varscan2
- MROH2B | c.4047C>T p.I1349= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as rs763324790, COSV101270607, COSV68186501; called by muse, mutect2
- MTX1 | c.558G>T p.L186= | Silent (SNP) | VAF 24/178 reads (13%) | catalogued as COSV100003291; called by muse, mutect2, varscan2
- OR51F1 | c.741C>T p.F247= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as rs1564905090, COSV58580387; called by muse, mutect2
- PCDHB16 | c.1722G>A p.E574= | Silent (SNP) | VAF 74/162 reads (46%) | catalogued as rs1183179230, COSV99501607; called by muse, mutect2, varscan2
- RBM23 | c.741A>T p.R247= (on ENST00000359890 / NM_001077351.2; = p.R231= on NM_018107.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/204 reads (14%) | catalogued as COSV100321345; called by muse, mutect2, varscan2
- SIGLEC12 | c.1518G>A p.R506= (on ENST00000291707 / NM_053003.4; = p.R388= on NM_033329.2) | Silent (SNP) | VAF 16/129 reads (12%) | catalogued as rs1181757179, COSV99389186; called by muse, mutect2, varscan2
- ST18 | c.2808G>C p.L936= | Silent (SNP) | VAF 14/208 reads (7%) | catalogued as COSV99388941; called by muse, mutect2
- TM4SF5 | c.593G>A p.*198= | Silent (SNP) | VAF 14/112 reads (13%) | catalogued as COSV99564618; called by muse, mutect2, varscan2
- TP53BP2 | c.702C>T p.L234= (on ENST00000343537 / NM_001031685.3; = p.L105= on NM_005426.2) | Silent (SNP) | VAF 26/133 reads (20%) | catalogued as rs1218047983, COSV59072848; called by muse, mutect2, varscan2
- WDR33 | c.1176A>T p.S392= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV100459783; called by muse, varscan2
- ZNF606 | c.1983C>T p.F661= | Silent (SNP) | VAF 16/142 reads (11%) | catalogued as rs746380631, COSV100071701; called by muse, varscan2
- ANKRD20A4P | c.*2C>T | 3'UTR (SNP) | VAF 25/138 reads (18%) | catalogued as rs1202626120, COSV100628479; called by muse, mutect2, varscan2
- CLDN16 | c.-24C>T | 5'UTR (SNP) | VAF 31/173 reads (18%) | catalogued as rs1277041944, COSV99290069; called by muse, mutect2, varscan2
- DCAKD | c.316+206T>C | Intron (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100149467; called by muse, mutect2
- MIR384 | n.56C>G | RNA (SNP) | VAF 13/81 reads (16%) | called by muse, mutect2, varscan2
- UHMK1 | c.-1G>A | 5'UTR (SNP) | VAF 9/97 reads (9%) | catalogued as COSV99966184; called by muse, mutect2, varscan2
- ZNF99 | c.*71G>C | 3'UTR (SNP) | VAF 10/98 reads (10%) | catalogued as COSV101233769, COSV68057953; called by muse, mutect2
